Somatic mutation profile of tumor specimen MP2PRT-PAVYRT-TMP1-A (aliquot MP2PRT-PAVYRT-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAVYRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,304 days).
Specimen MP2PRT-PAVYRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c2b032a-c10a-480d-a338-76283d89be7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYRT-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4d74b00-1a1f-4c17-b95b-3878a11bb88d

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, Frame Shift Del 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 28/142 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- BCL9 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 55/277 reads (20%) | catalogued as COSV52350345; called by muse, mutect2, varscan2
- CDS1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs1553903405, COSV55688119; called by muse, mutect2, varscan2
- DGKK | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782801964, COSV101052875; called by muse, mutect2, varscan2
- IGKV3-15 | c.345del p.P115del | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | catalogued as rs1362692308; called by mutect2, pindel*, varscan2
- KDR | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771235; called by muse, mutect2, varscan2
- PHACTR4 | c.1976G>A p.R659Q (on ENST00000373839 / NM_001350159.2; = p.R669Q on NM_023923.4) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779879547; called by muse, mutect2, varscan2
- TENT5A | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1197718099; called by muse, mutect2
- AP5M1 | c.655T>G p.S219A | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1GALT1C1L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/141 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CDC42BPG | c.3536G>T p.C1179F | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR1 | c.7390del p.E2464Rfs*5 | Frame Shift Del (DEL) | VAF 56/228 reads (25%) | called by mutect2, pindel, varscan2
- LZTR1 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SMAD7 | c.515C>A p.S172* | Nonsense Mutation (SNP) | VAF 22/674 reads (3%) | called by muse, mutect2
- GABRB1 | c.1197C>T p.S399= | Silent (SNP) | VAF 66/452 reads (15%) | catalogued as COSV99782214; called by muse, mutect2, varscan2
- GZMK | c.249C>T p.G83= | Silent (SNP) | VAF 61/397 reads (15%) | catalogued as rs150389257; called by muse, mutect2, varscan2
- KCNG4 | c.921C>T p.Y307= | Silent (SNP) | VAF 48/267 reads (18%) | catalogued as rs753022623, COSV100377205; called by muse, mutect2, varscan2
- TRPM6 | c.841+50G>A | Intron (SNP) | VAF 59/350 reads (17%) | called by muse, mutect2, varscan2
